Somatic mutation profile of tumor specimen MP2PRT-PATJHE-TMP1-A (aliquot MP2PRT-PATJHE-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATJHE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,368 days).
Specimen MP2PRT-PATJHE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46337655-8016-407e-9d2b-30ad0a97594a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJHE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJHE-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ac97d63-bbaa-4b33-9874-263037a1931a

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Nonsense Mutation 2, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.372G>C p.L124F | Missense Mutation (SNP) | VAF 32/793 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99797339; called by muse, mutect2
- CCDC83 | c.1044G>C p.M348I (on ENST00000342404 / NM_001286159.2; = p.M379I on NM_173556.5) | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54701989; called by muse, mutect2, varscan2
- CLCA2 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100991640; called by muse, mutect2, varscan2
- DYNC2H1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs561232842, COSV62086954; ClinVar: likely benign; called by muse, mutect2
- KLHDC8A | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as COSV100903863, COSV65679077; called by muse, mutect2
- LONRF3 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 147/834 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs1425143981; called by muse, mutect2, varscan2
- NLRX1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99066761; called by muse, mutect2
- POU2AF1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 28/601 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67577090; called by muse, mutect2
- SERTAD3 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 36/620 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV59324629; called by muse, mutect2
- SKIL | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 46/416 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.231); catalogued as COSV52059092; called by muse, mutect2, varscan2
- SLC17A2 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV55352466; called by muse, mutect2
- SLC26A3 | c.1702C>G p.L568V | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs143677801; called by muse, mutect2, varscan2
- TLR9 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 139/473 reads (29%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as COSV100645762; called by muse, mutect2, varscan2
- VEGFD | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 49/491 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52909399; called by muse, mutect2
- APBB1IP | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP20 | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 18/515 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2
- ATL1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- CCDC168 | c.3559G>A p.G1187R | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CEP19 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2
- CNOT2 | c.1407G>C p.W469C | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL1A1 | c.3745G>C p.E1249Q | Missense Mutation (SNP) | VAF 46/716 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2
- DENND11 | c.324C>G p.F108L | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- DNAH2 | c.4321G>A p.E1441K | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ECT2L | c.1839G>C p.Q613H | Missense Mutation (SNP) | VAF 27/471 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- FOXM1 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1328 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 48/560 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2
- MAGEA8 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 75/587 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- MMADHC | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- MROH1 | c.4592C>A p.S1531* | Nonsense Mutation (SNP) | VAF 27/651 reads (4%) | called by muse, mutect2
- PGM5 | c.1217T>A p.I406N | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PKHD1L1 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.034); called by muse, mutect2
- SLC39A5 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 49/666 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TANC2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, varscan2
- UBP1 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 25/645 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2
- USP27X | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 54/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBTB18 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 52/513 reads (10%) | called by muse, mutect2, varscan2
- ARID1B | c.5733G>A p.R1911= | Silent (SNP) | VAF 24/622 reads (4%) | called by muse, mutect2
- ATP2A3 | c.1473G>A p.R491= | Silent (SNP) | VAF 43/386 reads (11%) | called by muse, mutect2, varscan2
- CALY | c.105C>T p.I35= | Silent (SNP) | VAF 23/689 reads (3%) | called by muse, mutect2
- DLG5 | c.3693G>A p.L1231= | Silent (SNP) | VAF 34/670 reads (5%) | called by muse, mutect2
- HPGD | c.528G>A p.V176= | Silent (SNP) | VAF 41/278 reads (15%) | catalogued as COSV56662119; called by muse, mutect2, varscan2
- IGSF9 | c.2772C>G p.L924= (on ENST00000368094 / NM_001135050.2; = p.L908= on NM_020789.4) | Silent (SNP) | VAF 39/734 reads (5%) | called by muse, mutect2
- LRP5 | c.2850C>T p.F950= | Silent (SNP) | VAF 40/406 reads (10%) | called by muse, mutect2
- PEX2 | c.918G>A p.*306= | Silent (SNP) | VAF 27/263 reads (10%) | called by mutect2, varscan2
- SMAD9 | c.567C>G p.L189= | Silent (SNP) | VAF 46/728 reads (6%) | catalogued as COSV63206696; called by muse, mutect2
- TAF6 | c.84C>T p.I28= | Silent (SNP) | VAF 54/530 reads (10%) | catalogued as rs957139683, COSV59840383; called by muse, mutect2, varscan2
- TMEM168 | c.255T>C p.F85= | Silent (SNP) | VAF 57/367 reads (16%) | called by muse, mutect2, varscan2
- UBR3 | c.2727C>G p.L909= | Silent (SNP) | VAF 50/487 reads (10%) | catalogued as rs1216549486; called by muse, mutect2
- UGT2B4 | c.1512G>A p.V504= | Silent (SNP) | VAF 23/471 reads (5%) | catalogued as COSV100522770, COSV59318714; called by muse, mutect2
- ZC3H7B | c.2685C>T p.L895= | Silent (SNP) | VAF 20/417 reads (5%) | catalogued as COSV100687805; called by muse, mutect2
- CTBP1 | c.195+318C>G | Intron (SNP) | VAF 75/681 reads (11%) | catalogued as rs1475801999; called by muse, mutect2
- IGHV3-20 | chr14:106210935 ins GGA | 3'Flank (INS) | VAF 39/84 reads (46%) | called by mutect2, pindel, varscan2
